Surgical pathology report (de-identified scan), TCGA case TCGA-D7-6820, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D7-6820-01A (Primary Tumor).

Department of Cancer Pathology (cito)

copy No. 1

Date:

Examination: Histopathological examination

Internal invoice No.

Value of diagnostic procedure

Examination No.:

Patient: XXX

PESEL: XXX

Age:

Gender:

Material: **1. Multiple organ resection – stomach**

Unit in charge:

Physician in charge:

Material collected on:

Material received on:

Expected time of examination:

Clinical diagnosis: **Gastric cancer**

Examination performed on:

Macroscopic description:

The collected material consisting of the stomach, after being incised along the greater curvature, sized 19.8 x 10.8 cm with the omentum sized 43 x 28 cm.

Tumour sized 3.4 x 4.8 x 2.3 cm found on the front wall. Distance from the proximal boundary is 8.1 cm, from distal one, 4.6 cm.

Microscopic description:

Adenocarcinoma tubulopapillare invasivum ventriculi (G2). (intest

Tumour penetrating the mucous membrane and the muscular wall. It does not spread onto the peritoneum nor infiltrate the omentum.

Incision lines are within healthy volume.

Omentum – hyperaemia.

Stomach outside the tumour:

Lymph nodes:

- pericardial: Lymphonodis reactiva No (II).
- lesser curvature: Metastases earcinomatosa in lymphonodis No (II / V).
- greater curvature: metastases earcinomatosa in lymphonodis No (III / V).
- peripyloric: Lymphonodis reactiva No (II).

Histopathological Diagnosis:

Adenocarcinoma tubulopapillare invasivum ventriculi (G2). Invasive tubulopapillar adenocarcinoma of the stomach. pT2, pN1.

Metastases carcinomatosa in lymphonodis. Cancer metastases in the lymph nodes. No V / XIV.

Compliance validated by:

CONTACT YOUR DOCTOR WITH THIS REPORT!

Source: NCI Genomic Data Commons file 951b34b9-6825-40e8-a19b-61a27e422e3f (TCGA-D7-6820.4DAC657C-4A70-49F9-8C27-8F7022625158.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).